Somatic mutation profile of tumor specimen 0DI6KW from CCDI case PBBUGV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 13.7 years (5,009 days).
Specimen 0DI6KW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 604eb1c0-8818-4fbe-adf1-f61fe840fda8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06708d63-7690-4cdf-8235-787f02bd08c1

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Nonsense Mutation 1, Silent 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCNKA | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767511689; called by muse, mutect2, varscan2
- DICER1 | c.5438A>T p.E1813V | Missense Mutation (SNP) | VAF 88/792 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by mutect2, varscan2
- TRIM66 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1313317277; called by muse, mutect2
- MGAM | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 117/1048 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH7 | c.2935C>T p.R979* | Nonsense Mutation (SNP) | VAF 47/400 reads (12%) | called by muse, varscan2
- SPIRE1 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- VPS13A | c.5806A>G p.S1936G | Missense Mutation (SNP) | VAF 133/1328 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, varscan2
- PARP10 | c.717A>T p.S239= | Silent (SNP) | VAF 55/470 reads (12%) | called by muse, mutect2, varscan2
- CTNNA1 | c.1899+81C>T | Intron (SNP) | VAF 16/94 reads (17%) | catalogued as rs1028307653; called by muse, mutect2, varscan2
- DDX55 | c.*24C>A | 3'UTR (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- LTO1 | c.-64C>T | 5'UTR (SNP) | VAF 9/115 reads (8%) | catalogued as rs964475848; called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- MICAL1 | c.1856-75G>T | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
